Somatic mutation profile of tumor specimen HCM-BROD-0029-C71-86A (aliquot HCM-BROD-0029-C71-86A-01D-A80U-36) from HCMI case HCM-BROD-0029-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.0 years (21,192 days).
Specimen HCM-BROD-0029-C71-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8293fd07-4035-4741-83c8-c7d6777bef71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0029-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0029-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c211b70c-3dca-4680-adc4-611bc64a474e

The open-access MAF lists 80 somatic variants for this specimen: 60 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 18, Frame Shift Del 7, Splice Site 2, Intron 2, In Frame Del 2, Splice Region 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 133/136 reads (98%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 84/174 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFM | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 205/418 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769742032; called by muse, mutect2, varscan2
- ASS1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 266/525 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs373239430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1orf68 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 189/405 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs553642846; called by muse, mutect2, varscan2
- CDC20 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 219/390 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371111819; called by muse, mutect2, varscan2
- COL6A2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 364/736 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142880107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDR2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 214/459 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759709680, COSV63370740, COSV63375402; called by muse, mutect2, varscan2
- KCNG2 | c.1363_1365del p.D455del | In Frame Del (DEL) | VAF 255/598 reads (43%) | catalogued as rs1032453831; called by pindel, varscan2
- LOXHD1 | c.6614G>A p.R2205H (on ENST00000642948; = p.R2143H on NM_144612.7) | Missense Mutation (SNP) | VAF 242/518 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as rs531043544, COSV56067084; called by muse, varscan2
- LRRC43 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 271/819 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs758327800, COSV60289293; called by muse, mutect2, varscan2
- LZTR1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 284/616 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1390048261, CD151200, COSV53147042, COSV53148013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 53/730 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as rs749033340, COSV50729602, COSV50766538; called by muse, mutect2
- NRK | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 87/87 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1407667614; called by muse, mutect2, varscan2
- OR52K2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 245/485 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs757200117, COSV57835270; called by muse, mutect2, varscan2
- ORMDL1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 241/489 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1344520389; called by muse, mutect2, varscan2
- PDZD2 | c.6911C>T p.T2304M | Missense Mutation (SNP) | VAF 183/371 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as rs771660997; called by muse, mutect2, varscan2
- RBBP8NL | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 407/1180 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752143359; called by muse, mutect2, varscan2
- RGS20 | c.845C>T p.T282I (on ENST00000297313 / NM_170587.4; = p.T135I on NM_003702.4) | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs144684508; called by muse, mutect2, varscan2
- SLC16A5 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 291/590 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as rs372714521, COSV104395527; called by muse, mutect2, varscan2
- SPG11 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs764680914, COSV55990571; called by muse, mutect2, varscan2
- TJP3 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 142/328 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as rs146857520; called by muse, mutect2, varscan2
- TXNDC2 | c.227G>A p.R76H (on ENST00000306084 / NM_001098529.2; = p.R9H on NM_032243.6) | Missense Mutation (SNP) | VAF 270/513 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.392); catalogued as rs183239518, COSV60152030; called by muse, mutect2, varscan2
- ZNF560 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 232/504 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs377042499; called by muse, mutect2, varscan2
- ABCA7 | c.5306T>A p.L1769Q | Missense Mutation (SNP) | VAF 219/480 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ABCG2 | c.818C>A p.A273D | Missense Mutation (SNP) | VAF 16/367 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- AHCYL1 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 178/386 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ARHGAP5 | c.3943G>T p.D1315Y (on ENST00000345122 / NM_001030055.2; = p.D1314Y on NM_001173.3) | Missense Mutation (SNP) | VAF 124/124 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ATG2B | c.4142_4161+15del p.X1381_splice | Splice Site (DEL) | VAF 88/230 reads (38%) | called by mutect2, pindel, varscan2
- ATP8B1 | c.1010T>C p.M337T | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- B3GNT4 | c.46del p.R16Gfs*34 | Frame Shift Del (DEL) | VAF 194/734 reads (26%) | called by mutect2, pindel, varscan2
- CEP85L | c.1359_1362del p.E454Ffs*12 | Frame Shift Del (DEL) | VAF 105/181 reads (58%) | called by pindel, varscan2
- CNTNAP2 | c.1017C>A p.S339R | Missense Mutation (SNP) | VAF 188/617 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CSN3 | c.26del p.N9Mfs*5 | Frame Shift Del (DEL) | VAF 45/115 reads (39%) | called by mutect2, pindel, varscan2
- FAT1 | c.8705C>A p.A2902D | Missense Mutation (SNP) | VAF 172/420 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by mutect2, varscan2
- GALK2 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 147/294 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LRRC4B | c.1227C>A p.Y409* | Nonsense Mutation (SNP) | VAF 313/605 reads (52%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH2B | c.3867C>A p.L1289= | Splice Region (SNP) | VAF 119/266 reads (45%) | called by muse, mutect2, varscan2
- MUC1 | c.2917del p.S973Qfs*138 (on ENST00000611571 / NM_001371720.1; = p.S186Qfs*138 on NM_001204285.2) | Frame Shift Del (DEL) | VAF 358/862 reads (42%) | called by mutect2, pindel, varscan2
- NID2 | c.2877C>A p.H959Q | Missense Mutation (SNP) | VAF 231/232 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- NOL8 | c.335del p.G112Vfs*6 | Frame Shift Del (DEL) | VAF 209/536 reads (39%) | called by mutect2, pindel, varscan2
- NRDC | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 118/286 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52I1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 250/573 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.415); called by muse, varscan2
- PDILT | c.1627A>G p.K543E | Missense Mutation (SNP) | VAF 265/515 reads (51%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEG3 | c.3887A>G p.E1296G | Missense Mutation (SNP) | VAF 261/484 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- PIK3R4 | c.814T>A p.F272I | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- SCRIB | c.4346C>G p.P1449R | Missense Mutation (SNP) | VAF 32/660 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SPATC1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 323/694 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYT2 | c.1053+1G>C p.X351_splice | Splice Site (SNP) | VAF 15/392 reads (4%) | called by muse, mutect2
- TBC1D22B | c.564del p.K188Nfs*13 | Frame Shift Del (DEL) | VAF 128/414 reads (31%) | called by mutect2, pindel, varscan2
- TENM2 | c.3406G>T p.V1136L (on ENST00000518659 / NM_001122679.2; = p.V904L on NM_001080428.3) | Missense Mutation (SNP) | VAF 111/287 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- THAP2 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 220/388 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TLR7 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNKS | c.3345_3350del p.D1115_K1116del | In Frame Del (DEL) | VAF 82/201 reads (41%) | called by mutect2, pindel, varscan2
- TRIM77 | c.962A>C p.N321T | Missense Mutation (SNP) | VAF 191/396 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2A3 | c.1267T>A p.L423I | Missense Mutation (SNP) | VAF 194/396 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- UTP14C | c.1247_1256del p.E416Gfs*40 | Frame Shift Del (DEL) | VAF 127/369 reads (34%) | called by mutect2, pindel, varscan2
- WNK2 | c.5482G>A p.A1828T (on ENST00000297954 / NM_001282394.1; = p.A1791T on NM_006648.3) | Missense Mutation (SNP) | VAF 433/819 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ZNF236 | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 20/640 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABHD17B | c.690T>C p.I230= | Silent (SNP) | VAF 130/271 reads (48%) | catalogued as rs756745882; called by muse, mutect2, varscan2
- APOL2 | c.723A>G p.P241= | Silent (SNP) | VAF 268/575 reads (47%) | called by muse, mutect2, varscan2
- BCL11A | c.888G>A p.P296= (on ENST00000335712 / NM_001365609.1; = p.P330= on NM_018014.4) | Silent (SNP) | VAF 281/539 reads (52%) | catalogued as rs747182714; called by muse, mutect2, varscan2
- CR2 | c.2577C>T p.N859= | Silent (SNP) | VAF 139/281 reads (49%) | catalogued as rs776361702, COSV65505901; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRLF1 | c.276C>T p.N92= | Silent (SNP) | VAF 385/789 reads (49%) | catalogued as rs775994224, COSV66505392, COSV66505845; called by muse, mutect2, varscan2
- DEPDC1 | c.2382A>G p.T794= (on ENST00000456315 / NM_001114120.3; = p.T510= on NM_017779.6) | Silent (SNP) | VAF 176/365 reads (48%) | called by muse, mutect2, varscan2
- DNAH7 | c.2994C>T p.D998= | Silent (SNP) | VAF 222/415 reads (53%) | called by muse, mutect2, varscan2
- FAT1 | c.8706C>A p.A2902= | Silent (SNP) | VAF 172/421 reads (41%) | called by mutect2, varscan2
- ITGAM | c.909C>T p.I303= | Silent (SNP) | VAF 198/421 reads (47%) | catalogued as rs374273074; called by muse, mutect2, varscan2
- JCAD | c.2889C>T p.N963= | Silent (SNP) | VAF 244/497 reads (49%) | catalogued as rs769402502; called by muse, mutect2, varscan2
- NCAPH | c.504C>T p.R168= | Silent (SNP) | VAF 241/519 reads (46%) | catalogued as rs770891599; called by muse, mutect2, varscan2
- ORM1 | c.99C>T p.N33= | Silent (SNP) | VAF 133/462 reads (29%) | catalogued as rs759696863; called by muse, mutect2
- PARP15 | c.708G>A p.P236= | Silent (SNP) | VAF 209/410 reads (51%) | catalogued as rs368678964; called by muse, mutect2, varscan2
- SERPINA3 | c.954C>A p.I318= | Silent (SNP) | VAF 28/458 reads (6%) | catalogued as COSV67585586; called by muse, mutect2
- SLC3A2 | c.1164C>T p.I388= | Silent (SNP) | VAF 190/418 reads (45%) | catalogued as rs756682904; called by muse, mutect2, varscan2
- TRPM2 | c.384C>T p.G128= | Silent (SNP) | VAF 171/400 reads (43%) | catalogued as rs143653746; called by muse, mutect2, varscan2
- VPS33A | c.1371G>A p.T457= | Silent (SNP) | VAF 299/928 reads (32%) | catalogued as rs754744464, COSV57355859, COSV99931261; called by muse, mutect2, varscan2
- ZAR1L | c.450C>T p.D150= | Silent (SNP) | VAF 351/690 reads (51%) | called by muse, mutect2, varscan2
- NEDD4L | c.297+3907C>T | Intron (SNP) | VAF 443/860 reads (52%) | catalogued as rs1000425094; called by muse, mutect2, varscan2
- ZNF783 | c.802+3363G>A | Intron (SNP) | VAF 385/1199 reads (32%) | called by muse, mutect2, varscan2
